Somatic mutation profile of tumor specimen TCGA-EL-A3GR-01A (aliquot TCGA-EL-A3GR-01A-21D-A202-08) from TCGA case TCGA-EL-A3GR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.8 years (11,598 days).
Specimen TCGA-EL-A3GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81053f78-be0d-4b49-a199-0e4622e385d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GR-10A (Blood Derived Normal), aliquot TCGA-EL-A3GR-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710faa6f-fd20-40c2-b5c9-d3f1b8b2ac5f

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARC | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.024); catalogued as COSV63079087; called by muse, mutect2, varscan2
- NUDT12 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs1168418477, COSV50092084; called by muse, mutect2, varscan2
- PCNX4 | c.899G>C p.G300A (on ENST00000406854 / NM_001330177.2; = p.G66A on NM_022495.5) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.052); catalogued as COSV100471027, COSV58305659; called by muse, mutect2, varscan2
- PRPS1 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV65054549; called by muse, mutect2, varscan2
- STAG1 | c.1506G>C p.M502I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV52617561; called by muse, mutect2
- THPO | c.548T>G p.L183R (on ENST00000649095 / NM_001290003.1; = p.L43R on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52610639; called by muse, mutect2, varscan2
- ATP7A | c.4458_4461del p.L1487Wfs*23 | Frame Shift Del (DEL) | VAF 107/361 reads (30%) | called by pindel, varscan2
- DHX8 | c.1467C>G p.L489= | Silent (SNP) | VAF 118/320 reads (37%) | catalogued as COSV52255120; called by muse, mutect2, varscan2
